CCDI case PBBRWZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4c932a91-5b62-4f03-afb5-517a3d7fa4d0

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,784 days).

Biospecimens (4 samples)
- Sample 0DF6VC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DF6VG, 0DFBLR (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DF6VK: Tissue type: Tumor; Specimen type: Solid Tissue.
